Surgical pathology report (de-identified scan), TCGA case TCGA-A3-A6NL, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-A6NL-01A (Primary Tumor).

Surgical Pathology Final Report

Immunohistochemistry

Final Diagnosis

Left kidney, resection:

Renal cell carcinoma, conventional clear cell type.

Fuhrman grade 2.

Tumor size: 5.3 cm in greatest dimension.

Tumor appears confined to the kidney.

No extension into perirenal fat.

No lymphovascular invasion.

No renal vein invasion.

Negative vascular margin.

Negative ureteral margin.

Benign adrenal gland.

AJCC pathologic staging data: pT1b,NX.

ICD-O-3

Carcinoma, renal
cell, clear cell NOS

8312/3
Site (L) Kidney NOS
C64.9

Q7 7/22/13

Clinical Information

Left kidney mass.

Gross Description

"A, Left kidney." The specimen consists of a 219 gram, 11.6 x 6.2 x 5.5 cm kidney with a small amount of attached perinephric fat. Attached to the kidney is a 2 cm in length x 0.4 cm in diameter portion of ureter. The cortical surface is gray-pink. The specimen has previously been bivalved and there is a 5.3 x 4.8 x 4.1 cm soft yellow-tan focally hemorrhagic mass which grossly appears to abut the cortical surface and comes to within 0.1 cm of the surrounding fat. The surrounding fat has been inked black. The mass does not grossly appear to involve the collecting system. There is no dilatation or compression of the collecting system by the mass. The remaining renal parenchyma is red-tan and mildly congested. No additional masses or areas of interest are grossly identified. Adherent to the kidney is a 3 x 0.9 x 0.3 cm yellow-tan portion of adrenal gland. The previously described renal mass comes to within 0.1 cm of the adrenal gland. The adrenal gland has a yellow-brown cut surface and no masses or areas of interest are grossly identified. Lymphoid tissue is not grossly identified at the renal hilum. "A1," ureter and vascular margins; "A2," renal mass with adjacent radial margin; "A3-A4," renal mass; "A5," renal mass with adjacent parenchyma; "A6," renal mass with adjacent adherent adrenal gland.

Received with the specimen for research purposes is 1 yellow cassette labeled
, and 1 blue cassette labeled

1 green cassette labeled

Performing Lab

Criteria	7/2/13	Yes	No
Review Initials	Date Reviewed: 7/2/13		

Source: NCI Genomic Data Commons file c03e9ca0-00f7-4304-b502-ad202b98578b (TCGA-A3-A6NL.50DE211D-4204-4128-8F94-794425A99D99.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).